Somatic mutation profile of tumor specimen C3L-02346-01 (aliquot CPT0112460009) from CPTAC case C3L-02346, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 69.5 years (25,391 days).
Specimen C3L-02346-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0808625-aa8f-4c11-bb34-476f7c122cae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02346-31 (Blood Derived Normal), aliquot CPT0115150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0528ee5a-0249-4db6-9d1f-94fd58299dda

The open-access MAF lists 129 somatic variants for this specimen: 85 protein-altering or splice-affecting, 30 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 30, Nonsense Mutation 10, Intron 6, 5'Flank 4, Frame Shift Del 3, RNA 2, 3'UTR 1, In Frame Del 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PBRM1 | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | hotspot (GDC flag); catalogued as COSV56262126; called by muse, mutect2
- VHL | c.351G>A p.W117* | Nonsense Mutation (SNP) | VAF 49/247 reads (20%) | hotspot (GDC flag); catalogued as rs727504215, CM951286, HM971481, COSV56543268, COSV56548239, COSV56550455, COSV56553411; called by muse, mutect2, varscan2
- ADAMTS6 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV66865435; called by muse, mutect2, varscan2
- ARHGEF38 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs1376739132; called by mutect2, varscan2
- C2CD2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs774168838, COSV61599836; called by muse, mutect2, varscan2
- CHKB | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 34/489 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs577953900, COSV56415464; ClinVar: uncertain significance; called by muse, mutect2
- ERBB4 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 15/199 reads (8%) | catalogued as COSV61482964; called by muse, mutect2
- ERC2 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55668803, COSV55669829; called by muse, mutect2, varscan2
- FSHR | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 29/195 reads (15%) | catalogued as COSV58628376; called by muse, mutect2, varscan2
- GGCX | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 56/736 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.717); catalogued as rs568608275, COSV52088543; called by muse, mutect2
- HSF5 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV60418556; called by mutect2, varscan2
- KRTAP26-1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs200409291; called by muse, mutect2, varscan2
- LRP2 | c.12117G>T p.M4039I | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV55563270; called by muse, mutect2
- LRP4 | c.5428G>A p.V1810I | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.053); catalogued as rs779299308, COSV101066351; called by muse, mutect2
- MYH6 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV62452699; called by muse, mutect2, varscan2
- MYO18B | c.5989C>T p.R1997W | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765093050, COSV59126672; called by muse, mutect2
- NCOR1 | c.7311T>G p.D2437E | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1199397979; called by muse, mutect2
- NUMA1 | c.5966G>A p.R1989Q | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV52622264, COSV99474873; called by muse, mutect2, varscan2
- PCDHGA2 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 50/1028 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV53904851, COSV54010925; called by muse, mutect2
- POTEH | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 86/733 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as rs758952557, COSV58883447; called by muse, varscan2
- SATL1 | c.93G>A p.M31I (on ENST00000395409; = p.M218I on NM_001012980.2) | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1556386391; called by muse, mutect2, varscan2
- SLC24A3 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs150292821; called by muse, mutect2
- TAF2 | c.3108+1G>C p.X1036_splice | Splice Site (SNP) | VAF 18/257 reads (7%) | catalogued as COSV65419303; called by muse, mutect2
- TAS2R43 | c.529A>G p.M177V | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1478563142; called by muse, mutect2, varscan2
- TRIM64C | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 83/646 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs546301976; called by muse, mutect2, varscan2
- TTC29 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 33/498 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs367836405, COSV100284396; called by muse, mutect2
- ZKSCAN2 | c.2615C>A p.S872Y | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60158987; called by muse, mutect2, varscan2
- ZNF672 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 19/193 reads (10%) | catalogued as rs1322479356; called by muse, mutect2, varscan2
- ADRA2A | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- AFM | c.542T>A p.V181D | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- AHNAK | c.4874G>C p.G1625A | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- ASS1 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 73/530 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATF7IP | c.2909_2910del p.T970Nfs*3 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by pindel, varscan2
- ATM | c.5081C>A p.A1694E | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BPIFC | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- C17orf58 | c.130A>T p.I44F | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- CD164 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CELSR1 | c.2707G>T p.E903* | Nonsense Mutation (SNP) | VAF 29/217 reads (13%) | called by muse, mutect2, varscan2
- CEP250 | c.5980C>G p.L1994V | Missense Mutation (SNP) | VAF 45/614 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- CRISPLD2 | c.820A>G p.K274E | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- DHX37 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2
- DLG5 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DROSHA | c.3562G>T p.A1188S | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.349); called by muse, mutect2
- EPHA7 | c.1108A>G p.K370E | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FADS6 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.135); called by muse, mutect2
- FAM20B | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); called by muse, mutect2
- FBXW5 | c.254T>A p.V85E | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2
- FDFT1 | c.761T>G p.L254W | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2
- FLNC | c.6009C>G p.I2003M | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- GNB1L | c.963G>T p.W321C | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLPH3L | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRXCR1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF2F1 | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GULP1 | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIF27 | c.3548A>G p.H1183R | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- KMT2E | c.2242A>T p.K748* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2
- LEO1 | c.1543A>C p.T515P | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- LILRA1 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 67/433 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MARK1 | c.2037T>G p.S679R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, varscan2
- MARVELD2 | c.5C>G p.S2* | Nonsense Mutation (SNP) | VAF 20/237 reads (8%) | called by muse, mutect2
- MC1R | c.745_754del p.I249Sfs*62 | Frame Shift Del (DEL) | VAF 73/640 reads (11%) | called by mutect2, pindel
- MINPP1 | c.1313T>A p.L438* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | called by muse, varscan2
- NLRP11 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- OBSL1 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5K4 | c.508A>G p.R170G | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- OTULINL | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGB4 | c.1304G>C p.S435T | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- PCDHGC3 | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PHETA2 | c.195C>G p.S65R | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2
- PLEKHA1 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLXNB2 | c.552C>A p.S184R | Missense Mutation (SNP) | VAF 38/533 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PPP2R2A | c.35_43del p.W12_F14del | In Frame Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel
- PPP4R3B | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RAI1 | c.890A>T p.H297L | Missense Mutation (SNP) | VAF 85/556 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, varscan2
- SETD2 | c.1812_1813del p.N604Kfs*4 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- SIMC1 | c.2238T>G p.F746L (on ENST00000443967 / NM_001308196.1; = p.F331L on NM_198567.5) | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC39A7 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SNTB1 | c.548C>A p.A183E | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRIP6 | c.1412C>T p.T471I | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- VWF | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 42/628 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- ZAP70 | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZFP37 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF112 | c.65T>C p.L22P (on ENST00000337401 / NM_001083335.2; = p.L16P on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- ZNF587B | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRE3 | c.1953A>G p.K651= | Silent (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- AHNAK | c.7737C>T p.I2579= | Silent (SNP) | VAF 56/378 reads (15%) | called by muse, mutect2, varscan2
- ALK | c.4662A>C p.S1554= | Silent (SNP) | VAF 30/490 reads (6%) | called by muse, mutect2
- AMBN | c.1197T>C p.D399= | Silent (SNP) | VAF 41/267 reads (15%) | called by muse, mutect2, varscan2
- ANKLE1 | c.429C>A p.R143= (on ENST00000394458; = p.R89= on NM_152363.6) | Silent (SNP) | VAF 44/574 reads (8%) | called by muse, mutect2
- ARHGAP45 | c.705T>A p.P235= | Silent (SNP) | VAF 55/430 reads (13%) | called by muse, mutect2, varscan2
- CFAP46 | c.8013G>A p.A2671= | Silent (SNP) | VAF 28/370 reads (8%) | catalogued as rs543143409, COSV104371588; called by muse, mutect2
- CFTR | c.2959C>T p.L987= | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, varscan2
- DGKZ | c.135C>G p.S45= | Silent (SNP) | VAF 16/372 reads (4%) | catalogued as COSV58988171; called by muse, mutect2
- FNBP4 | c.2670A>G p.P890= | Silent (SNP) | VAF 46/313 reads (15%) | called by muse, mutect2, varscan2
- GAL3ST2 | c.498C>T p.S166= | Silent (SNP) | VAF 28/442 reads (6%) | catalogued as rs752388528; called by muse, mutect2
- GALK2 | c.99T>A p.I33= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- GBX2 | c.957G>A p.R319= | Silent (SNP) | VAF 42/321 reads (13%) | called by muse, mutect2, varscan2
- ILF3 | c.1785C>G p.A595= | Silent (SNP) | VAF 46/468 reads (10%) | called by muse, mutect2
- KRT3 | c.882C>A p.I294= | Silent (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- LAMB3 | c.102T>A p.L34= | Silent (SNP) | VAF 84/671 reads (13%) | called by muse, mutect2, varscan2
- LTBR | c.45G>A p.G15= | Silent (SNP) | VAF 40/228 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.33726T>C p.P11242= | Silent (SNP) | VAF 16/207 reads (8%) | called by muse, mutect2
- NELFB | c.1611C>T p.F537= | Silent (SNP) | VAF 55/277 reads (20%) | catalogued as rs1440044130, COSV58026488; called by muse, mutect2, varscan2
- PDHA2 | c.318A>T p.I106= | Silent (SNP) | VAF 20/338 reads (6%) | catalogued as COSV99756728; called by muse, mutect2
- PRRC2B | c.6666C>A p.V2222= | Silent (SNP) | VAF 28/338 reads (8%) | called by muse, mutect2
- RPS14 | c.171T>C p.T57= | Silent (SNP) | VAF 30/265 reads (11%) | called by muse, mutect2, varscan2
- RTL1 | c.1389C>T p.D463= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs966617899, COSV101128303; called by muse, mutect2
- SLC8A3 | c.2157C>T p.S719= (on ENST00000381269 / NM_183002.3; = p.S717= on NM_033262.4) | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs904956224, COSV99385938; called by muse, mutect2, varscan2
- STK33 | c.1482A>G p.Q494= | Silent (SNP) | VAF 121/512 reads (24%) | catalogued as rs747773173, COSV59401505; called by muse, mutect2, varscan2
- TAF5 | c.438G>A p.A146= | Silent (SNP) | VAF 42/334 reads (13%) | called by muse, mutect2, varscan2
- TDRKH | c.1662C>T p.N554= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as rs747184908; called by muse, mutect2, varscan2
- USP41 | c.39C>T p.Y13= | Silent (SNP) | VAF 42/266 reads (16%) | catalogued as rs759666810; called by muse, mutect2, varscan2
- VASH1 | c.795C>T p.H265= | Silent (SNP) | VAF 20/376 reads (5%) | catalogued as rs558923372; called by muse, mutect2
- ZNF497 | c.852G>T p.V284= | Silent (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- ADGRA1 | chr10:133084845 G>A | 5'Flank (SNP) | VAF 58/381 reads (15%) | catalogued as rs749533254; called by muse, mutect2, varscan2
- B4GALNT3 | c.2061-1186T>A | Intron (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- BCAR4 | n.1080A>C | RNA (SNP) | VAF 32/340 reads (9%) | called by muse, mutect2
- CCDC107 | chr9:35657958 G>A | 5'Flank (SNP) | VAF 26/188 reads (14%) | catalogued as rs1353190924; called by muse, mutect2, varscan2
- DST | c.4297-1638G>A | Intron (SNP) | VAF 71/502 reads (14%) | called by muse, mutect2, varscan2
- GABPB1 | c.-1+377T>C | Intron (SNP) | VAF 75/547 reads (14%) | called by muse, mutect2, varscan2
- GTF2A1 | c.338-1037T>C | Intron (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- ITGB5 | chr3:124887778 A>C | 5'Flank (SNP) | VAF 7/38 reads (18%) | called by muse, varscan2
- LINC01537 | n.86G>A | RNA (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- MDH2 | chr7:76048096 C>A | 5'Flank (SNP) | VAF 93/426 reads (22%) | catalogued as rs1005998547, COSV50392069; called by muse, mutect2, varscan2
- NDUFA10 | c.1000-12460G>T | Intron (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.-147+12145C>A | Intron (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- WDR87 | c.-7G>C | 5'UTR (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- ZNF827 | c.*406G>A | 3'UTR (SNP) | VAF 53/384 reads (14%) | catalogued as rs561734416; called by muse, mutect2, varscan2
